Somatic mutation profile of tumor specimen ALCH-B2TK-TTP1-A (aliquot ALCH-B2TK-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2TK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 41.5 years (15,170 days).
Specimen ALCH-B2TK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ab3c5ed-531a-49fc-b840-f32f003cc202.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2TK-NB1-A (Blood Derived Normal), aliquot ALCH-B2TK-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d600463-586c-4e69-b103-d591d84106d1

The open-access MAF lists 166 somatic variants for this specimen: 119 protein-altering or splice-affecting, 26 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 26, Nonsense Mutation 10, Intron 7, 3'UTR 6, RNA 4, 5'Flank 3, Splice Region 3, Splice Site 2, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1801C>T p.R601W | Missense Mutation (SNP) | VAF 36/313 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770453522, COSV50260672; called by muse, mutect2, varscan2
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100917752; called by muse, mutect2
- AGAP4 | c.1286G>T p.S429I | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs781927586; called by muse, mutect2
- AXIN1 | c.1919A>G p.E640G | Missense Mutation (SNP) | VAF 34/398 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51987574; called by muse, mutect2
- CCDC141 | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 30/543 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV55378079, COSV55380367; called by muse, mutect2
- CCDC17 | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV51972660; called by muse, mutect2
- ELF3 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1236669171; called by muse, mutect2
- FCRL5 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs775998452, COSV62520826; called by muse, mutect2, varscan2
- GLB1 | c.1628C>A p.S543* | Nonsense Mutation (SNP) | VAF 33/494 reads (7%) | catalogued as COSV56567291; called by muse, mutect2
- GRIN2A | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58051262; called by muse, mutect2
- GSC | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs200899998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HECTD2 | c.1204G>A p.D402N | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV53219327; called by muse, mutect2, varscan2
- KCNC2 | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as COSV54376355; called by muse, mutect2
- MPP2 | c.876C>G p.N292K (on ENST00000461854 / NM_001278372.2; = p.N268K on NM_005374.5) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99290393; called by muse, mutect2, varscan2
- MROH1 | c.3955C>T p.R1319* | Nonsense Mutation (SNP) | VAF 36/386 reads (9%) | catalogued as rs1326966387; called by muse, mutect2
- MTUS2 | c.1390A>C p.K464Q | Missense Mutation (SNP) | VAF 55/426 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV70915793; called by muse, mutect2, varscan2
- NIBAN3 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs150700269, COSV56306554; called by muse, mutect2, varscan2
- PRG4 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 108/687 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs753207228; called by muse, mutect2, varscan2
- PRKD1 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs754654624; called by muse, varscan2
- RORB | c.885G>T p.M295I (on ENST00000396204 / NM_001365023.1; = p.M284I on NM_006914.4) | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100974614; called by muse, mutect2
- RPA3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs749246644, COSV56189411; called by muse, mutect2, varscan2
- SCN4B | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 71/590 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs1352900290, COSV61252926; called by muse, mutect2, varscan2
- SLC52A3 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs537244674; called by muse, mutect2, varscan2
- TBC1D10C | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100408401; called by muse, mutect2, varscan2
- TNXB | c.12913G>A p.V4305M (on ENST00000647633; = p.V4058M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/863 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763223867; called by muse, mutect2
- TRIM36 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as rs1203582578; called by muse, mutect2, varscan2
- UGT8 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs141798376; called by muse, mutect2, varscan2
- UNC79 | c.1250G>T p.G417V (on ENST00000393151 / NM_001346218.2; = p.G240V on NM_020818.5) | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99827010; called by muse, mutect2
- WIPI2 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV56588290, COSV56588593; called by muse, mutect2
- ZNF804B | c.3514C>A p.Q1172K | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60834246; called by muse, mutect2
- ZNF813 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs756610238; called by muse, mutect2
- AASS | c.31A>G p.R11G | Missense Mutation (SNP) | VAF 40/403 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- ACOD1 | c.734_745del p.F245_N248del | In Frame Del (DEL) | VAF 33/352 reads (9%) | called by mutect2, pindel
- ADAR | c.3014A>G p.E1005G | Missense Mutation (SNP) | VAF 21/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKT3 | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 16/205 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- APOB | c.4885G>A p.D1629N | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- APPL2 | c.414T>C p.N138= | Splice Region (SNP) | VAF 10/239 reads (4%) | called by muse, mutect2
- ARHGAP31 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 39/395 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ARHGAP31 | c.2042C>A p.P681Q | Missense Mutation (SNP) | VAF 40/413 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); called by muse, mutect2
- ARHGEF6 | c.1705-2A>T p.X569_splice | Splice Site (SNP) | VAF 19/357 reads (5%) | called by muse, mutect2
- ARMH4 | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2
- ASPM | c.5230G>C p.V1744L | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- CDA | c.153dup p.G52Rfs*16 | Frame Shift Ins (INS) | VAF 13/116 reads (11%) | called by mutect2, pindel
- CDC26 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- CENPL | c.709A>T p.T237S | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CFAP65 | c.3386G>T p.R1129L | Missense Mutation (SNP) | VAF 28/335 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); called by muse, mutect2
- CHGA | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.69); called by muse, mutect2
- CIT | c.2861A>T p.N954I | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.178); called by muse, mutect2
- CNIH3 | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 47/379 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.963); called by muse, varscan2
- COL6A5 | c.6391C>T p.P2131S (on ENST00000312481; = p.P2127S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD1 | c.4253G>A p.C1418Y (on ENST00000520002; = p.C1417Y on NM_033225.6) | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CST1 | c.100A>T p.I34F | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); called by muse, mutect2
- CTDP1 | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CYP4A22 | c.1291T>C p.F431L | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- DFFA | c.519C>G p.H173Q | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2
- EPHA6 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- FOXRED2 | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); called by muse, mutect2
- HECTD4 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 27/380 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- HNRNPA2B1 | c.254C>A p.S85* (on ENST00000354667 / NM_031243.3; = p.S73* on NM_002137.4) | Nonsense Mutation (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2, varscan2
- HS3ST4 | c.1321C>A p.Q441K | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- HSF4 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ISM1 | c.1321A>T p.N441Y | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF15 | c.3171G>A p.E1057= | Splice Region (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- KLHL32 | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.049); called by muse, mutect2
- KLRC2 | c.235A>T p.I79F | Missense Mutation (SNP) | VAF 51/799 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- KRTAP13-4 | c.277C>A p.R93S | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LINGO1 | c.1338C>A p.C446* | Nonsense Mutation (SNP) | VAF 23/177 reads (13%) | called by muse, mutect2, varscan2
- LNX1 | c.1262del p.G421Vfs*10 (on ENST00000263925 / NM_001126328.3; = p.G325Vfs*10 on NM_032622.2) | Frame Shift Del (DEL) | VAF 29/288 reads (10%) | called by mutect2, pindel, varscan2
- MACF1 | c.7638A>T p.L2546F | Missense Mutation (SNP) | VAF 22/223 reads (10%) | called by muse, mutect2
- MAST3 | c.1620G>T p.V540= | Splice Region (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- MPO | c.231C>A p.Y77* | Nonsense Mutation (SNP) | VAF 112/510 reads (22%) | called by muse, mutect2, varscan2
- MROH2B | c.454T>C p.C152R | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MS4A1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- MS4A3 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MSN | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2
- MYH7 | c.3280A>G p.I1094V | Missense Mutation (SNP) | VAF 52/487 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- MYRFL | c.1141T>A p.Y381N | Missense Mutation (SNP) | VAF 23/411 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- N4BP1 | c.1420G>C p.V474L | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- NCOR1 | c.4741+1G>A p.X1581_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | called by muse, varscan2
- NEO1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NEUROD4 | c.728A>T p.D243V | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- NGDN | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- NKX2-2 | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- NOD1 | c.2377A>G p.K793E | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- P3H1 | c.444C>A p.Y148* | Nonsense Mutation (SNP) | VAF 30/280 reads (11%) | called by muse, mutect2
- PARVB | c.1087G>T p.V363L | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.7042A>T p.M2348L | Missense Mutation (SNP) | VAF 32/823 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- PKHD1 | c.1341G>C p.L447F | Missense Mutation (SNP) | VAF 32/455 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2
- PLA2G2A | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 41/440 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.282); called by muse, mutect2
- PLEKHA6 | c.3128G>A p.S1043N | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- PLEKHM1 | c.2392C>G p.Q798E | Missense Mutation (SNP) | VAF 27/425 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); called by muse, mutect2
- PRODH2 | c.358C>T p.L120F (on ENST00000301175; = p.L44F on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PRTG | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 20/209 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); called by muse, mutect2
- RASAL1 | c.2045A>T p.H682L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBMXL2 | c.148G>T p.G50C | Missense Mutation (SNP) | VAF 81/603 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBMXL3 | c.2881A>G p.S961G | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROBO3 | c.2703C>A p.C901* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- SLC26A1 | c.908C>A p.T303K | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX5 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.346); called by muse, mutect2
- SPTBN4 | c.4054G>T p.E1352* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | called by muse, mutect2, varscan2
- TEX14 | c.2253T>A p.D751E (on ENST00000240361 / NM_001201457.2; = p.D745E on NM_031272.5) | Missense Mutation (SNP) | VAF 29/399 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- TF | c.1899C>A p.D633E | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2
- TLL2 | c.923G>T p.R308I | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TM4SF4 | c.374G>C p.S125T | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMC3 | c.1582T>G p.F528V | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- TMEM169 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 62/599 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM43 | c.43T>A p.C15S | Missense Mutation (SNP) | VAF 33/506 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIM54 | c.844C>A p.Q282K (on ENST00000380075 / NM_187841.3; = p.Q324K on NM_032546.4) | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- TRIM77 | c.1346C>G p.S449C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TRPM2 | c.2887G>A p.V963M | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- TTC6 | c.1109A>G p.D370G (on ENST00000267368; = p.D1736G on NM_001310135.3) | Missense Mutation (SNP) | VAF 34/348 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.31207T>C p.F10403L (on ENST00000591111; = p.F9476L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/238 reads (5%) | PolyPhen benign (0); called by muse, mutect2
- ZNF248 | c.413A>G p.K138R | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- ZNF587 | c.1348C>G p.H450D | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- ZNF675 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.367); called by muse, mutect2
- ZSCAN26 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- ZSCAN31 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.056); called by muse, mutect2
- ZSCAN4 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADGRL3 | c.1182A>T p.V394= (on ENST00000506720 / NM_001322402.2; = p.V326= on NM_015236.6) | Silent (SNP) | VAF 21/194 reads (11%) | called by muse, mutect2, varscan2
- ANO7 | c.2172C>A p.A724= (on ENST00000274979; = p.A670= on NM_001370694.2) | Silent (SNP) | VAF 32/384 reads (8%) | called by muse, mutect2
- CACNA1S | c.4881C>T p.P1627= | Silent (SNP) | VAF 32/313 reads (10%) | called by muse, mutect2, varscan2
- CFAP54 | c.8076A>T p.T2692= | Silent (SNP) | VAF 9/169 reads (5%) | called by muse, mutect2
- CLPTM1L | c.882A>T p.A294= | Silent (SNP) | VAF 27/257 reads (11%) | called by muse, mutect2, varscan2
- COQ8B | c.1173G>T p.R391= | Silent (SNP) | VAF 36/398 reads (9%) | catalogued as rs1282586105; called by muse, mutect2
- CYP26C1 | c.981G>A p.V327= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- FYB1 | c.555A>G p.Q185= | Silent (SNP) | VAF 70/476 reads (15%) | catalogued as rs777873328; called by muse, mutect2, varscan2
- GFY | c.291G>T p.P97= | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as rs1474344302; called by muse, mutect2, varscan2
- GOLGA6L2 | c.844C>A p.R282= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as rs756013010, COSV61472961; called by mutect2, varscan2
- HECTD1 | c.372A>C p.V124= | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, mutect2, varscan2
- KDM6B | c.942A>G p.P314= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- LRRC17 | c.477T>G p.R159= | Silent (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- MYRFL | c.1902T>A p.A634= | Silent (SNP) | VAF 34/382 reads (9%) | called by muse, mutect2
- NPHP4 | c.555G>T p.L185= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs772023605; called by muse, varscan2
- NSMF | c.1263C>A p.L421= (on ENST00000371475 / NM_001130969.3; = p.L419= on NM_015537.4) | Silent (SNP) | VAF 101/485 reads (21%) | called by muse, mutect2, varscan2
- OR2G3 | c.244T>C p.L82= | Silent (SNP) | VAF 40/254 reads (16%) | called by muse, mutect2, varscan2
- OR4K15 | c.846T>C p.Y282= (on ENST00000305051; = p.Y258= on NM_001005486.1) | Silent (SNP) | VAF 18/318 reads (6%) | catalogued as rs140044773; called by muse, mutect2
- PLEKHG2 | c.3801T>A p.R1267= | Silent (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- PLXND1 | c.5391C>T p.V1797= | Silent (SNP) | VAF 30/295 reads (10%) | called by muse, mutect2, varscan2
- SCN2A | c.1536A>G p.E512= | Silent (SNP) | VAF 49/556 reads (9%) | catalogued as rs201680546; ClinVar: benign / likely benign; called by muse, mutect2
- SIX4 | c.642C>T p.F214= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- SNAPC4 | c.4155C>T p.G1385= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs576998607; called by muse, mutect2, varscan2
- TLR6 | c.2226C>T p.N742= | Silent (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- TNN | c.2061C>T p.H687= | Silent (SNP) | VAF 28/368 reads (8%) | catalogued as rs370669454, COSV53422792; called by muse, mutect2
- WDFY3 | c.4416C>T p.I1472= | Silent (SNP) | VAF 22/209 reads (11%) | catalogued as rs146868524; called by muse, mutect2
- AC024940.1 | n.2774C>A | RNA (SNP) | VAF 30/290 reads (10%) | called by muse, mutect2, varscan2
- AL450442.1 | n.783G>T | RNA (SNP) | VAF 18/273 reads (7%) | called by muse, mutect2
- AMH | c.*24C>A | 3'UTR (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- C2orf49 | c.-45C>T | 5'UTR (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- DENND1B | c.83-20560G>A | Intron (SNP) | VAF 48/538 reads (9%) | called by muse, mutect2
- E2F7 | c.988+373A>T | Intron (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- EXOC5 | c.*2736G>A | 3'UTR (SNP) | VAF 19/323 reads (6%) | called by muse, mutect2
- FAH | c.*35A>G | 3'UTR (SNP) | VAF 32/418 reads (8%) | called by muse, mutect2
- FAM124B | c.732+586T>G | Intron (SNP) | VAF 48/424 reads (11%) | called by muse, mutect2, varscan2
- GNAO1 | c.161+1584G>A | Intron (SNP) | VAF 24/440 reads (5%) | catalogued as COSV52614413; called by muse, mutect2
- H3-3B | chr17:75784728 C>A | 5'Flank (SNP) | VAF 73/333 reads (22%) | catalogued as COSV53143945, COSV99505490; called by muse, mutect2, varscan2
- MTERF4 | chr2:241102311 C>A | 5'Flank (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- OR2M2 | chr1:248179984 T>C | 5'Flank (SNP) | VAF 14/87 reads (16%) | called by muse, varscan2
- OR5P1P | n.196T>A | RNA (SNP) | VAF 10/84 reads (12%) | called by muse, varscan2
- PDE1C | c.980+17A>G | Intron (SNP) | VAF 23/427 reads (5%) | called by muse, mutect2
- PLXNA1 | c.4363-18A>G | Intron (SNP) | VAF 36/347 reads (10%) | called by muse, mutect2, varscan2
- RNF170 | c.*206G>A | 3'UTR (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- RPL11 | c.7-36G>T | Intron (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- TAL1 | c.*15C>A | 3'UTR (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- UBE3D | c.*71A>T | 3'UTR (SNP) | VAF 56/456 reads (12%) | called by muse, mutect2, varscan2
- ZNF204P | n.656G>A | RNA (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
